Somatic mutation profile of tumor specimen 9462caa5-13e8-4997-a4f7-294f16 (aliquot 9462caa5-13e8-4997-a4f7-294f16_D6_1) from CPTAC case 20BR002, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90.0 years (32,872 days).
Specimen 9462caa5-13e8-4997-a4f7-294f16: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c234702-91c4-41a6-a177-e5266bd6642c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ea2fbf6a-45bc-445b-9bd1-341311 (Blood Derived Normal), aliquot ea2fbf6a-45bc-445b-9bd1-341311_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3576fea-6cbf-4684-9ed9-c5d395d99d27

The open-access MAF lists 155 somatic variants for this specimen: 105 protein-altering or splice-affecting, 31 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 31, RNA 8, Nonsense Mutation 6, Intron 5, Frame Shift Del 4, 5'Flank 3, 3'Flank 2, In Frame Del 2, Splice Site 2, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG8 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 87/334 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs763000556; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACLY | c.2041G>A p.V681I | Missense Mutation (SNP) | VAF 81/142 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.264); catalogued as rs201998406; called by mutect2, varscan2
- ACOD1 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs138681467; called by muse, mutect2, varscan2
- ARHGEF11 | c.1985G>A p.R662K | Missense Mutation (SNP) | VAF 74/376 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV59358753; called by muse, mutect2, varscan2
- BRINP1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 82/282 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56297833; called by muse, mutect2, varscan2
- BTAF1 | c.2134C>G p.Q712E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV56435327; called by muse, mutect2, varscan2
- CA2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 54/423 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs143666045; called by muse, mutect2, varscan2
- CAD | c.5274G>C p.W1758C | Missense Mutation (SNP) | VAF 20/371 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV53027648; called by muse, mutect2
- COL7A1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 21/619 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs942152368, COSV60395020; called by muse, mutect2
- CT47B1 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 85/346 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs780236702, COSV100989019; called by muse, mutect2, varscan2
- EVC | c.1939C>T p.R647W | Missense Mutation (SNP) | VAF 139/543 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770276380, COSV53835082; called by muse, mutect2, varscan2
- FBXW7 | c.860A>G p.E287G (on ENST00000281708 / NM_001349798.2; = p.E207G on NM_018315.5) | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55897632; called by muse, mutect2, varscan2
- FLNB | c.2131G>T p.V711L | Missense Mutation (SNP) | VAF 77/528 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1201338015; called by muse, mutect2, varscan2
- FSCN1 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as rs1228866091; called by muse, mutect2, varscan2
- GREB1L | c.4431G>C p.Q1477H | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs1165745245; called by muse, mutect2, varscan2
- GRM1 | c.3340G>A p.E1114K | Missense Mutation (SNP) | VAF 96/437 reads (22%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.079); catalogued as rs778743909, COSV51202675; called by muse, mutect2, varscan2
- HP | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 179/379 reads (47%) | catalogued as rs758923371, COSV100577583, COSV63326271; called by muse, mutect2, varscan2
- KCNA10 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 31/630 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370455162; called by muse, mutect2
- KLRC1 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as rs1426185999; called by muse, mutect2, varscan2
- KRTAP13-1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs763603199, COSV100819897, COSV62663095; called by muse, mutect2, varscan2
- MIEF2 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 70/629 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs755220310, COSV59902507; called by muse, mutect2, varscan2
- MPP3 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT tolerated (0.36); PolyPhen probably damaging (1); catalogued as COSV68198526; called by muse, mutect2
- NLRP7 | c.1946C>A p.T649N | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs1432726123; called by muse, mutect2, varscan2
- NRCAM | c.2542G>C p.A848P (on ENST00000379028 / NM_001371124.1; = p.A832P on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as COSV61047126; called by muse, mutect2
- OR2A25 | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101376329; called by muse, mutect2, varscan2
- OR6K2 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.177); catalogued as rs1470130530, COSV62743233; called by muse, mutect2
- PRR36 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0.03); catalogued as rs1004693591; called by muse, mutect2, varscan2
- PTEN | c.224A>C p.H75P | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.377); catalogued as COSV64304283; called by muse, mutect2, varscan2
- PTPRQ | c.4564G>A p.E1522K (on ENST00000616559; = p.E1480K on NM_001145026.2) | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.396); catalogued as rs1455656996, COSV57048175; called by muse, mutect2, varscan2
- RIMS1 | c.2875G>A p.G959S | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.783); catalogued as rs763404266; called by muse, mutect2, varscan2
- SBF1 | c.2695G>A p.G899S | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs1300163820; called by muse, mutect2
- SCGB1C1 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57293981; called by muse, mutect2, varscan2
- SLCO2B1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 127/293 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs543049597, COSV56935587; called by muse, mutect2, varscan2
- SLCO4A1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs1447598529, COSV53890824; called by muse, mutect2
- SORCS3 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139171852, COSV100864980; called by muse, mutect2, varscan2
- SSH2 | c.3446C>T p.T1149I | Missense Mutation (SNP) | VAF 253/412 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as rs1367446941; called by muse, mutect2, varscan2
- TIGD2 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57648706; called by muse, mutect2, varscan2
- TP53 | c.838del p.R280Efs*65 | Frame Shift Del (DEL) | VAF 456/676 reads (67%) | catalogued as COSV52662754, COSV52708728, COSV52851287; called by mutect2, varscan2
- TRIM77 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs368829617; called by muse, mutect2, varscan2
- TSBP1 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 18/173 reads (10%) | catalogued as rs149451141; called by muse, mutect2
- UNC5CL | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs147879961; called by muse, mutect2
- WNT9A | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752190826; called by muse, mutect2
- ZNF676 | c.1739T>G p.L580R (on ENST00000650058; = p.L548R on NM_001001411.3) | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68092204; called by muse, mutect2, varscan2
- ABCB9 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 99/649 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM32 | c.2142A>C p.E714D | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ADNP2 | c.2435T>G p.V812G | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AFF3 | c.1393A>T p.K465* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- ANKRD30A | c.2701C>G p.Q901E (on ENST00000611781; = p.Q845E on NM_052997.2) | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- ANKRD36B | c.2593G>C p.E865Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.04); called by mutect2, varscan2
- ARHGEF40 | c.4061C>T p.A1354V | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CACNA1E | c.449T>C p.F150S | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCNB3 | c.1091A>T p.K364M | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP112 | c.2223C>G p.N741K | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- CRLF3 | c.1160T>A p.V387E | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- DDR1 | c.2279T>C p.L760P (on ENST00000324771; = p.L723P on NM_001954.4) | Missense Mutation (SNP) | VAF 74/651 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.2454G>C p.M818I | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- DNAH5 | c.12910A>T p.S4304C | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2
- DNAJC14 | c.1750A>G p.I584V | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); called by muse, mutect2
- EML3 | c.836G>C p.C279S | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ENOSF1 | c.1132A>T p.M378L (on ENST00000340116 / NM_001354066.2; = p.M344L on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.7); called by muse, mutect2
- FBLN2 | c.179_193del p.Q60_C65delinsR | In Frame Del (DEL) | VAF 104/460 reads (23%) | called by mutect2, pindel, varscan2
- FHDC1 | c.2754G>T p.R918S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2
- FLOT1 | c.15T>A p.C5* | Nonsense Mutation (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- FMN2 | c.4682A>T p.E1561V | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FMOD | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 10/243 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GAA | c.2042C>A p.P681H | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GMPPB | c.1011C>G p.Y337* (on ENST00000308388 / NM_021971.4; = p.Y364* on NM_013334.3) | Nonsense Mutation (SNP) | VAF 88/380 reads (23%) | called by muse, mutect2, varscan2
- GPR146 | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 110/694 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- GPRIN1 | c.232G>C p.G78R | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- GRM8 | c.1086C>A p.F362L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- HAS1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIF16B | c.3367G>A p.E1123K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- LRRC45 | c.1402-2A>C p.X468_splice | Splice Site (SNP) | VAF 26/302 reads (9%) | called by muse, mutect2
- MCM10 | c.1147G>A p.E383K (on ENST00000484800 / NM_182751.3; = p.E382K on NM_018518.5) | Missense Mutation (SNP) | VAF 16/459 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.42); called by muse, mutect2
- MIB1 | c.1862G>C p.R621T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- MINPP1 | c.1313T>G p.L438* | Nonsense Mutation (SNP) | VAF 54/218 reads (25%) | called by muse, mutect2, varscan2
- MS4A12 | c.328T>C p.C110R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2
- MTIF2 | c.1745T>C p.I582T | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MUC17 | c.2377G>C p.G793R | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MYH14 | c.2740C>G p.R914G | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- NCAPG2 | c.1327-2A>G p.X443_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- NUP210 | c.4453dup p.A1485Gfs*54 | Frame Shift Ins (INS) | VAF 80/405 reads (20%) | called by mutect2, pindel, varscan2
- OR2T2 | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 107/1053 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2
- OTUD4 | c.1729G>C p.V577L (on ENST00000447906 / NM_001366057.1; = p.V512L on NM_001102653.1) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- PDE6D | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/93 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PPCDC | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PPP2R2B | c.611C>G p.T204S (on ENST00000394409; = p.T270S on NM_181674.2) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PROSER1 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMD4 | c.812G>C p.G271A | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRK | c.1050A>C p.L350F | Missense Mutation (SNP) | VAF 57/394 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RUNX1T1 | c.1793C>A p.T598N (on ENST00000265814 / NM_001198628.1; = p.T571N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.069); called by muse, mutect2
- SCMH1 | c.304T>C p.W102R (on ENST00000326197 / NM_001031694.2; = p.W55R on NM_012236.4) | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SIDT2 | c.2295C>G p.F765L | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO6A1 | c.1930A>C p.I644L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.082); called by muse, mutect2
- SPTBN1 | c.6967_6973del p.S2323Afs*97 | Frame Shift Del (DEL) | VAF 37/213 reads (17%) | called by mutect2, pindel, varscan2
- TMIGD3 | c.425C>G p.S142C (on ENST00000369717 / NM_001081976.2; = p.S223C on NM_020683.7) | Missense Mutation (SNP) | VAF 91/523 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- TRIM68 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- UNC5CL | c.1108A>G p.T370A | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2
- USP49 | c.1209del p.L404Sfs*35 | Frame Shift Del (DEL) | VAF 38/346 reads (11%) | called by mutect2, pindel, varscan2
- WDR27 | c.2173G>C p.V725L | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WNK2 | c.5974_5988del p.K1992_L1996del (on ENST00000297954 / NM_001282394.1; = p.K1955_L1959del on NM_006648.3) | In Frame Del (DEL) | VAF 44/324 reads (14%) | called by mutect2, varscan2
- ZNF133 | c.1270A>G p.T424A (on ENST00000316358 / NM_001352454.2; = p.T423A on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF486 | c.1041_1042del p.K348Tfs*5 | Frame Shift Del (DEL) | VAF 24/187 reads (13%) | called by pindel, varscan2
- ZNF529 | c.1574A>C p.Q525P | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZNF560 | c.2030C>T p.T677I | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1860C>A p.S620= | Silent (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- ADCY10 | c.2265G>C p.T755= | Silent (SNP) | VAF 36/630 reads (6%) | catalogued as COSV63242505, COSV63242550; called by muse, mutect2
- ALG10 | c.558G>C p.R186= | Silent (SNP) | VAF 33/208 reads (16%) | called by muse, mutect2, varscan2
- BCAN | c.174C>T p.H58= | Silent (SNP) | VAF 13/248 reads (5%) | called by muse, mutect2
- BCL7C | c.258T>C p.P86= | Silent (SNP) | VAF 36/268 reads (13%) | called by muse, mutect2, varscan2
- BRD4 | c.1164C>T p.H388= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as rs200443528; called by muse, mutect2, varscan2
- CARF | c.1749A>C p.V583= | Silent (SNP) | VAF 35/132 reads (27%) | called by muse, mutect2, varscan2
- CCDC130 | c.327C>T p.Y109= | Silent (SNP) | VAF 37/156 reads (24%) | catalogued as rs1231826222; called by muse, mutect2, varscan2
- CLEC19A | c.246C>T p.S82= | Silent (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- CSNK2A2 | c.6C>G p.P2= | Silent (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- EBF2 | c.363G>A p.T121= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV68777755; called by muse, mutect2, varscan2
- HERC4 | c.537T>C p.T179= | Silent (SNP) | VAF 17/148 reads (11%) | called by muse, mutect2, varscan2
- ITGA6 | c.3072C>T p.A1024= (on ENST00000442250; = p.A985= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/708 reads (4%) | catalogued as rs764393153; called by muse, mutect2
- KIF26B | c.651G>A p.S217= | Silent (SNP) | VAF 31/597 reads (5%) | catalogued as rs745665621; called by muse, mutect2
- MGAM2 | c.2373C>T p.I791= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as rs1237847152; called by muse, mutect2, varscan2
- MTUS1 | c.1821C>G p.A607= | Silent (SNP) | VAF 23/231 reads (10%) | catalogued as rs375815032, COSV50550554, COSV50554803; called by muse, mutect2, varscan2
- MTUS2 | c.1050G>T p.G350= | Silent (SNP) | VAF 14/284 reads (5%) | catalogued as COSV70916394; called by muse, mutect2
- NOS2 | c.726G>A p.S242= | Silent (SNP) | VAF 18/191 reads (9%) | catalogued as rs770268351; called by muse, mutect2
- PDZRN3 | c.1911G>A p.G637= | Silent (SNP) | VAF 103/583 reads (18%) | called by muse, mutect2, varscan2
- POLQ | c.1227A>G p.V409= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1463446401; called by muse, mutect2, varscan2
- PPM1B | c.1104T>C p.S368= | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, varscan2
- PRPF8 | c.5583C>T p.I1861= | Silent (SNP) | VAF 214/690 reads (31%) | catalogued as rs780838844, COSV100517481; called by muse, mutect2, varscan2
- S1PR1 | c.753G>A p.S251= | Silent (SNP) | VAF 24/574 reads (4%) | catalogued as COSV59514567; called by muse, mutect2
- SMYD3 | c.975C>A p.I325= (on ENST00000490107 / NM_001375962.1; = p.I266= on NM_022743.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/758 reads (6%) | catalogued as COSV63628713; called by muse, mutect2
- TAGLN3 | c.300G>A p.A100= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as rs529078455; called by muse, mutect2
- TRHDE | c.2796T>A p.G932= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- TRIM50 | c.1416G>A p.P472= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as rs1256013179; called by muse, mutect2, varscan2
- TULP4 | c.978C>T p.F326= | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as COSV100893188; called by muse, mutect2, varscan2
- UCK2 | c.621C>T p.I207= | Silent (SNP) | VAF 11/300 reads (4%) | catalogued as COSV63314368; called by muse, mutect2
- ZNF630 | c.852T>C p.I284= | Silent (SNP) | VAF 5/116 reads (4%) | called by muse, mutect2
- ZNF692 | c.144C>T p.S48= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs749393918; called by muse, mutect2, varscan2
- AC092656.1 | n.431A>T | RNA (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2
- AC092656.1 | n.429T>C | RNA (SNP) | VAF 24/143 reads (17%) | called by muse, mutect2
- ADGRE4P | n.1397C>T | RNA (SNP) | VAF 54/243 reads (22%) | catalogued as rs547017173; called by muse, mutect2, varscan2
- AP000769.1 | n.196T>C | RNA (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504839 G>C | 5'Flank (SNP) | VAF 11/159 reads (7%) | called by muse, mutect2
- ATR | c.6553-9T>G | Intron (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- CLLU1 | chr12:92421169 G>T | 5'Flank (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- FBXL21P | n.1273T>C | RNA (SNP) | VAF 87/409 reads (21%) | called by muse, mutect2, varscan2
- JPH3 | c.382+800_382+802del | Intron (DEL) | VAF 5/53 reads (9%) | catalogued as rs757987606; called by pindel, varscan2*
- MIR7162 | chr10:30364785 G>A | 3'Flank (SNP) | VAF 65/385 reads (17%) | catalogued as rs768956322; called by muse, mutect2, varscan2
- MRPL20 | chr1:1399637 C>T | 3'Flank (SNP) | VAF 31/161 reads (19%) | called by muse, mutect2, varscan2
- PI4KAP2 | n.2634C>G | RNA (SNP) | VAF 28/348 reads (8%) | called by muse, mutect2
- RBBP4 | c.310+4693T>A | Intron (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159284 C>T | 5'Flank (SNP) | VAF 56/144 reads (39%) | catalogued as rs79409546; called by muse, mutect2, varscan2
- RPGR | c.1245+542A>G | Intron (SNP) | VAF 14/76 reads (18%) | catalogued as rs1297127594; called by muse, mutect2, varscan2
- SPATA31C1 | n.968A>G | RNA (SNP) | VAF 88/402 reads (22%) | called by muse, mutect2, varscan2
- SPOCK3 | c.190-36593G>C | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- SSPOP | n.14326C>T | RNA (SNP) | VAF 18/103 reads (17%) | catalogued as rs571742133, COSV100947476, COSV65130811; called by muse, mutect2, varscan2
- TNFRSF10B | c.*2337T>G | 3'UTR (SNP) | VAF 45/213 reads (21%) | called by muse, mutect2, varscan2
